Somatic mutation profile of tumor specimen MMRF_1267_1_BM_CD138pos (aliquot MMRF_1267_1_BM_CD138pos_T2_TSE61_K03762) from MMRF case MMRF_1267, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.8 years (14,542 days).
Specimen MMRF_1267_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 508e558b-0df8-48b4-8228-dd14cf4533ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1267_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1267_1_PB_Whole_C1_TSE61_K03763; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/902c393e-b26f-4b40-9c46-f074e4b700a2

The open-access MAF lists 33 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, 3'UTR 8, Silent 6, Frame Shift Ins 2, Intron 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 45/107 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BTBD9 | c.1052T>C p.I351T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs370716875; called by muse, mutect2, varscan2
- PIK3C2A | c.2609A>G p.D870G | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.538); catalogued as COSV99791376; called by muse, mutect2, varscan2
- VLDLR | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV66078333; called by muse, mutect2, varscan2
- BACH1 | c.322A>C p.K108Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CAMK2G | c.1097C>T p.P366L (on ENST00000423381 / NM_001367518.1; = p.P332L on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDCP1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.027); called by muse, mutect2
- DAAM1 | c.2677G>C p.D893H | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FAT3 | c.1684G>T p.V562F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAUS3 | c.461T>A p.I154N | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2
- MAST4 | c.7869G>C p.L2623F (on ENST00000403625 / NM_001164664.2; = p.L2434F on NM_015183.3) | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MKKS | c.1706A>C p.K569T | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP26 | c.1181T>G p.L394R | Missense Mutation (SNP) | VAF 38/39 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZDHHC21 | c.607_608insG p.I203Sfs*11 | Frame Shift Ins (INS) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.9517C>T p.P3173S | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF43 | c.294dup p.A99Sfs*7 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- ADAD1 | c.33G>A p.S11= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs201390867, COSV56641643; called by muse, mutect2, varscan2
- GPR37 | c.1365G>T p.T455= | Silent (SNP) | VAF 4/86 reads (5%) | catalogued as COSV58257290; called by muse, mutect2
- MOB2 | c.282C>T p.D94= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs758630667; called by muse, mutect2, varscan2
- NIPA2 | c.675C>G p.L225= | Silent (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- RP1 | c.984C>T p.D328= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as rs776574526, COSV55113924; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZBTB7C | c.1401C>A p.I467= | Silent (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- BACE1 | c.*2132A>G | 3'UTR (SNP) | VAF 38/75 reads (51%) | catalogued as rs1402004038; called by muse, mutect2, varscan2
- DCAF8 | c.-101+70C>G | Intron (SNP) | VAF 8/131 reads (6%) | catalogued as rs1309898586; called by muse, mutect2
- FYTTD1 | chr3:197749416 T>G | 5'Flank (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2, varscan2
- IMPA2 | c.*359C>A | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- LHFPL1 | c.*649dup | 3'UTR (INS) | VAF 34/35 reads (97%) | called by mutect2, varscan2
- MYO5A | c.*3857C>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs968250696; called by muse, mutect2
- NFRKB | c.*540T>A | 3'UTR (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- NLRC3 | c.*402G>A | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- TRIM9 | c.*1292G>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ZNF214 | c.-273G>A | 5'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, varscan2
- ZNF483 | c.*272C>A | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
